Surgical pathology report (de-identified scan), TCGA case TCGA-B0-5075, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-B0-5075-01A (Primary Tumor).

FINAL DIAGNOSIS:

PART 1. PERINEPHRIC ADIPOSE TISSUE, LEFT, "FAT OVERLYING TUMOR", PARTIAL NEPHRECTOMY - BENIGN FIBROADIPOSE TISSUE, NO TUMOR SEEN.

PART 2. KIDNEY, LEFT, PARTIAL NEPHRECTOMY -

- A. RENAL CELL CARCINOMA, CONVENTIONAL (CLEAR CELL) TYPE, 2.0 CM IN GREATEST DIMENSION, FUHRMANN NUCLEAR GRADE II/IV (see comment).**
- B. CARCINOMA FOCALLY EXTENDS INTO PERINEPHRIC FAT.**
- C. ALL SURGICAL RESECTION MARGINS ARE FREE OF TUMOR.**
- D. FOCAL LYMPHOVASCULAR INVASION IS PRESENT.**
- E. HISTOPATHOLOGIC STAGE T3a Nx Mx.**

COMMENT:

Tumor cells are positive for vimentin, renal cell carcinoma marker (RCC), CD10, and E-cadherin. Ki67 proliferative index is 1%. Tumor cells are negative for Hale's colloidal iron, c-kit, CK7, inhibin, and BerEP4. This immunohistochemical profile and the morphology are consistent with conventional renal cell carcinoma.

Source: NCI Genomic Data Commons file 9322988c-e19e-4d22-9cb9-25e8de42f707 (TCGA-B0-5075.5AA0FCE0-0139-4F80-B2BE-E6C8CB544F66.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).